Surgical pathology report (de-identified scan), TCGA case TCGA-NH-A6GB, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Candler, specimen TCGA-NH-A6GB-01A (Primary Tumor).

[page 1 of 3]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 1

User:

PATIENT:

ACCT #:

AGE/SX:

ROOM:

REG:

REG DR:

DOB:

BED:

DIS:

STATUS:

SPEC #:

RECD:

STATUS:

COLL:

TIME IN FORMALIN: 7:55 hrs.

CLINICAL INFORMATION:

Pre-Op Diagnosis: Colon cancer

Remarks:

Specimen(s): A. Retroperitoneal lymph node
B. Transverse colon

ICD-O-3

Adenocarcinoma NOS 8140/3
Site Transverse colon C18.4

GA 6/13/13

MICROSCOPIC DIAGNOSIS

A. RETROPERITONEAL LYMPH NODE, EXCISION:

- METASTATIC ADENOCARCINOMA CONSISTENT WITH METASTATIC COLON CARCINOMA

B. TRANSVERSE COLON, SEGMENTAL RESECTION:

- HIGH-GRADE ADENOCARCINOMA
- TUMOR MEASURES 4.5 CM IN GREATEST DIMENSION AND EXTENDS THROUGH THE COLON WALL INTO SUBSEROUS FAT (pT3)
- SURGICAL MARGINS OF RESECTION FREE OF TUMOR WITH CLOSEST MARGIN 2.5 CM RADIAL
- METASTATIC ADENOCARCINOMA IN 6 OF 12 SUBSEROUS LYMPH NODES
- SEE COMMENT FOR SURGICAL PATHOLOGY CANCER CASE SUMMARY CHECK LIST

COMMENT(S)

CAP APPROVED SURGICAL PATHOLOGY CANCER CASE SUMMARY: COLON AND RECTUM

SPECIMEN:

Transverse colon

PROCEDURE:

Transverse colectomy

TUMOR SITE:

Transverse colon

MACROSCOPIC TUMOR PERFORATION:

Not identified

HISTOLOGIC TYPE:

Adenocarcinoma

HISTOLOGIC GRADE:

High-grade

MICROSCOPIC TUMOR EXTENSION:

Tumor invades through the muscularis propria into the subserosal adipose tissue or the nonperitonealized pericolic or perirectal soft tissues but does not extend to the serosal surface

MARGINS:

Distance of invasive carcinoma from closest margin: 25 cm

Proximal margin: Uninvolved by invasive carcinoma

Distal margin: Uninvolved by invasive carcinoma

Circumferential or mesenteric margin: Uninvolved by invasive carcinoma

TREATMENT EFFECT:

No prior treatment

** CONTINUED ON NEXT PAGE **

[page 2 of 3]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 2

User:

SPEC #:

PATIENT:

COMMENT(S)

(Continued)

LYMPH-VASCULAR INVASION:	Not identified
PERINEURAL INVASION:	Not identified
PATHOLOGIC STAGING:	Primary tumor: pT3
	Regional lymph nodes: pN2b
	Number of lymph nodes examined: 13
	Number of lymph nodes involved: 7
	Distance metastasis: Not applicable

GROSS DESCRIPTION:

A. Received fresh for frozen section labeled with the patient's name and "retroperitoneal node" is a 1.7 x 1.5 x 0.5 cm ovoid tan lymph node. On cross section, the node has a pale grayish-tan color and focally contains an area suspicious for a metastasis. A representative section is submitted in block A1 for frozen section. A cytologic touch prep is prepared for Diff-Quik stain. The remainder of the tissue is submitted in block A2.

B. Received fresh for tissue banking and labeled with the patient's name and "transverse colon". Received is a 12.5 cm segment of large bowel. The large bowel is received with a 22.0 x 12.0 x 1.7 cm portion of yellow, lobulated, omental adipose. The attached omentum makes the specimen consistent with transverse colon. The segment of bowel is received unoriented between proximal and distal. There is a focal area of serosal puckering with "creeping fat". The area is inked blue and the bowel is opened to have a centrally ulcerated, 4.5 x 4.0 cm tumor mass. The tumor mass is nearly circumferential and has raised, rolled borders. The tumor comes to within 5 cm of one margin and 2.5 cm of the opposite margin. The tumor diffusely involves the bowel wall and focally extends through the bowel wall to superficially invade the underlying yellow adipose. The tumor focally appears to abut the inked serosa. There is 2.5 cm of yellow adipose between the tumor and the mesenteric fat resection margin. The surrounding mucosa is unremarkable with normal, tan folds. The fat is sectioned and scant, possible lymph nodes are identified.

Representative sections are sampled as labeled:

B1-B2	-	margins
B3	-	perpendicular sections of nearest radial fat margin
B4	-	representative sections of omental adipose
B5-B7	-	representative sections of tumor to include areas of deepest invasion and tumor to serosa
B8-B9	-	whole lymph nodes
B10	-	one lymph node bisected

MICROSCOPIC DESCRIPTION:

The slides are examined and evaluated.

** CONTINUED ON NEXT PAGE **

[page 3 of 3]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 3

SPEC #:

PATIENT:

(Continued)

INTRAOPERATIVE CONSULTATION:
FROZEN SECTION:

- A. RETROPERITONEAL LYMPH NODE:
- METASTATIC ADENOCARCINOMA CONSISTENT WITH COLORECTAL PRIMARY
- RESULTS GIVEN TO IN THE OPERATING ROOM AT

Signed ____ (signature on file) ____

** END OF REPORT **

Qualifying Primary Noted		
Reviewed Initial		

Source: NCI Genomic Data Commons file 13bc9f3e-304d-4e5c-bab7-1398712ed1fe (TCGA-NH-A6GB.163923CC-A65E-4F0F-83CC-D0CA33C8F35E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).